Gene-level copy-number profile of tumor specimen HCM-CSHL-0147-C24-01A from HCMI case HCM-CSHL-0147-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,924 days).
Specimen HCM-CSHL-0147-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b5b9fb0-42e2-430b-b247-7cf52d52f574.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0147-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/10cf058c-21c9-4fd8-8670-d34548673c65

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 404; copy number 2: 5,088; copy number 3: 11,490; copy number 4: 23,753; copy number 5: 8,418; copy number 6: 6,233; copy number 7: 2,281; copy number 8: 1,133; copy number 9: 18; copy number 10: 1; copy number 11: 57; copy number 16: 3; copy number 18: 25.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:183,037,665–183,040,119, 1 gene: CIBAR1P2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr11:127,204–139,612, 1 gene (within-gene range 0–4): LINC01001.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.
- chr22:21,207,973–21,227,637, 1 gene (within-gene range 0–2): GGT2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 104 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 10: CFHR3.
- chr18:21,704,957–21,870,953, 1 gene, copy number 18 (within-gene range 8–18): MIB1.
- chr18:21,793,883–23,586,506, 41 genes, copy number 11–18: RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA.
- chr18:26,655,737–27,190,698, 1 gene, copy number 9 (within-gene range 6–9): AQP4-AS1.
- chr18:26,822,341–26,825,171, 1 gene, copy number 9 (within-gene range 6–9): AC018371.1.
- chr18:26,852,043–28,824,826, 17 genes, copy number 9–16: AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1.
- chr18:34,493,290–36,279,119, 40 genes, copy number 11: DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3.
- chr19:27,638,483–27,646,483, 2 genes, copy number 9: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
